Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81A, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81A-01A (Primary Tumor).

Date receiving:

Clinical history

Left pheochromocytoma

Macroscopy

The piece of adrenalectomy weights 29g after dissection of adipose tissue and measures 7x2.5X3 cm. It is centred on a nodule measuring 3 cm along their longer axis, well limited, buff colour associated with some hemorrhagic alterations. Peri-adrenal tumor has a micro-nodular appearance.

Microscopy

The histological aspect is a monomorphic tumoral proliferation with trabecular architecture or nests (zellballen). It is densely cellular and composed by cells with basophilic cytoplasm, finely granular. The nuclei, of medium size, are rounded, finely nucleoled and non hyperchromatic. It is not observed quota of fusiform cells. There is no evidence of mitotic figures. This tumor is well limited by a thin discontinuous capsule. There is no evidence of infiltration of the capsule, of the peri-adrenal adipose tissue, of vascular invasion or tumor necrosis. The periphery of adrenal presents a draft cortical nodulation without hyperplasia of glomerulosa or medulla.

At the immunohistochemical study, the tumor cells are chromogranin positive. The sustentacular network is well preserved, highlighted by the PS100.

CONCLUSION

Left adrenal pheochromocytoma, 3 cm long axis
PASS score = 4 (high cellularity 2 cellular monotony 2).

Translated on from the original pathological report evaluated on .

ICD-O-3
Pheochromocytoma NOS 8700/3
Site Adrenal gland NOS C74.9
JAV 10/17/13

Source: NCI Genomic Data Commons file 62126b5b-ff90-4a6c-acba-75f57552437d (TCGA-WB-A81A.948A7624-9ED1-4510-83E9-7FCB231FFA82.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).